Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7855, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7855-01A (Primary Tumor).

Microscopic description

Sections demonstrate neoplasm consisting of increased cellularity and mild to moderate pleomorphism. The tissue demonstrates microcystic, myxoid areas. No necrosis is identified. Mitoses are focally increased to up to 4 mitoses per 10 high power fields. The majority of tumor neoplastic cells demonstrate intense P53 immunoreactivity. The MIB-1 labeling index ranges up to 98.7% in the most proliferative regions of tumor. Overall, the elevated MIB-1 labeling index in conjunction with the P53 immunoreactivity and the histologic features are consistent with an anaplastic astrocytoma.

Diagnosis

Anaplastic astrocytoma

Source: NCI Genomic Data Commons file 99268806-f448-40ba-8ea1-d374d376fceb (TCGA-HT-7855.77A245BA-4E68-4215-86D4-2CBA5A981189.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).